Surgical pathology report (de-identified scan), TCGA case TCGA-06-0126, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0126-01A (Primary Tumor).

06-0126

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY, LEFT FRONTAL LOBE: GLIOBLASTOMA MULTIFORME.
MIB-1: 25%

Operation/Specimen: UPDATED REPORT - Left posterior frontal tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: A. 0.4 cm tissue fragment.

INTRAOPERATIVE CONSULTATION: Glioma, in #1,2.

B.

SPECIMEN: Left posterior frontal tumor.
FIXATIVE: None.
GENERAL: A 1 x 0.9 x 0.2 cm. pink-tan rubbery soft tissue
fragment.
SECTIONS: 3, all submitted.

MICROSCOPIC: Sections show a high grade glioma with hypercellularity, mitotic figures, prominent endothelial hyperplasia and one fragment of necrotic tissue. These features are compatible with glioblastoma multiforme.

ADDENDUM REPORT: Result of immunostain (MIB-1):

With the MIB-1, the proliferation index of the tumor cells is about 25%.

Source: NCI Genomic Data Commons file 133c804d-ee1a-404c-9ac4-d8ee24c0b29b (TCGA-06-0126.2F9689CE-2E05-4508-95F5-D052680DAE36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).